Somatic mutation profile of cancer-model specimen HCM-BROD-0210-C71-85R (Adherent Cell Line, passage 8; aliquot HCM-BROD-0210-C71-85R-01D-A78T-36), derived from the recurrence tumor of HCMI case HCM-BROD-0210-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.6 years (19,586 days).
Specimen HCM-BROD-0210-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d078910-4ed6-4b39-87ae-ff85b31f1b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0210-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0210-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4941eb21-3fe1-4230-bcfa-96f130c6f768

The open-access MAF lists 94 somatic variants for this specimen: 59 protein-altering or splice-affecting, 23 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 23, Intron 5, Nonsense Mutation 5, Frame Shift Del 3, 5'Flank 2, 3'UTR 2, RNA 2, In Frame Del 1, Splice Region 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1166T>A p.L389* | Nonsense Mutation (SNP) | VAF 56/56 reads (100%) | catalogued as rs587778845, CM071074, COSV57298834, COSV99923545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 546/546 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.315-8G>A | Splice Region (SNP) | VAF 116/224 reads (52%) | catalogued as rs762655218, COSV62415799; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD30B | c.4024C>T p.R1342C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1432131805; called by muse, mutect2, varscan2
- ARHGEF6 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as rs1368379563; called by muse, mutect2, varscan2
- BLNK | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV56413269; called by muse, mutect2
- CACNA1B | c.6758G>A p.R2253Q | Missense Mutation (SNP) | VAF 217/441 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1232097200, COSV53147809; called by muse, mutect2, varscan2
- CDR1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs538565518; called by muse, mutect2, varscan2
- DCAF12L1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100948428, COSV64421531; called by muse, mutect2, varscan2
- DPT | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs148412326; called by muse, mutect2, varscan2
- DSG1 | c.1409A>G p.N470S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs933463366; called by muse, mutect2, varscan2
- DZIP3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs138409858; called by muse, mutect2, varscan2
- FAM81B | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV51984359; called by muse, mutect2
- GCNA | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 346/755 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs1292180999; called by muse, mutect2, varscan2
- IGKV2-24 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs775559803; called by muse, mutect2, varscan2
- INTS6L | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66086465; called by muse, mutect2, varscan2
- MAGED2 | c.1328G>A p.W443* | Nonsense Mutation (SNP) | VAF 22/412 reads (5%) | catalogued as rs1266386146; called by muse, mutect2
- MIB2 | c.2953G>A p.V985I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs945800678; called by muse, mutect2, varscan2
- MYLK3 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1432256739; called by muse, mutect2, varscan2
- MYOM1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 277/569 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1334526476; called by muse, mutect2, varscan2
- NOX3 | c.1541G>A p.W514* | Nonsense Mutation (SNP) | VAF 60/194 reads (31%) | catalogued as rs749685924, COSV50150407; called by muse, mutect2, varscan2
- OR10G3 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs752631358; called by muse, varscan2
- PTEN | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100909680, COSV64293534, COSV64307061; called by muse, mutect2, varscan2
- SCNN1B | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 33/423 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV56308401; called by muse, mutect2
- SERPINB7 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs750323054, COSV60532739; called by muse, mutect2, varscan2
- STRIP2 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 198/530 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376069671; called by muse, mutect2, varscan2
- TBX4 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 155/156 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748931901; called by muse, mutect2, varscan2
- TEKT5 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs370491307; called by muse, mutect2, varscan2
- AFF2 | c.2032C>G p.P678A | Missense Mutation (SNP) | VAF 146/319 reads (46%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ASB8 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 115/136 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP8B4 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BICC1 | c.1143del p.F381Lfs*15 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, pindel, varscan2
- BTBD7 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CARD11 | c.2487G>A p.M829I | Missense Mutation (SNP) | VAF 177/402 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2AIP | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- CLEC4F | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CMYA5 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- COMMD2 | c.127del p.I43Sfs*11 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- DIPK1A | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH3 | c.8933A>G p.K2978R | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2
- DNAH8 | c.1837A>C p.K613Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DNAH8 | c.3752A>T p.Y1251F | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ESYT1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 204/256 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- FAM135A | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2
- LEMD2 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MAFA | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 259/658 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MS4A14 | c.725A>T p.K242I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2
- NLRP12 | c.2281_2290del p.D761Qfs*4 | Frame Shift Del (DEL) | VAF 42/474 reads (9%) | called by mutect2, pindel
- PCDHGB1 | c.2372A>T p.D791V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDILT | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PHC3 | c.2530C>T p.P844S (on ENST00000494943 / NM_001308116.2; = p.P856S on NM_024947.4) | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RYR3 | c.13774G>A p.E4592K (on ENST00000389232; = p.E4593K on NM_001036.6) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHANK2 | c.1921_1936+1del p.X641_splice | Splice Site (DEL) | VAF 94/117 reads (80%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3329G>A p.S1110N | Missense Mutation (SNP) | VAF 54/996 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- SPHK2 | c.1656C>A p.D552E | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM51 | c.459_464del p.R153_L154del | In Frame Del (DEL) | VAF 59/98 reads (60%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 180/356 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- TRAJ9 | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- ZNF275 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB4 | c.3144C>T p.N1048= | Silent (SNP) | VAF 83/472 reads (18%) | catalogued as rs8187807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG3 | c.228C>T p.A76= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs745962811; called by muse, mutect2, varscan2
- C3 | c.1986C>T p.C662= | Silent (SNP) | VAF 50/556 reads (9%) | called by muse, mutect2
- CDKN2AIP | c.1398C>G p.L466= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- DNAH5 | c.165G>T p.V55= | Silent (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- FBLN1 | c.792C>T p.D264= | Silent (SNP) | VAF 138/339 reads (41%) | catalogued as rs144704783; called by muse, mutect2, varscan2
- LILRA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 78/161 reads (48%) | catalogued as rs149766788, COSV52491834; called by muse, mutect2, varscan2
- MCM3AP | c.2091C>T p.L697= | Silent (SNP) | VAF 305/632 reads (48%) | catalogued as rs371262030; called by muse, mutect2, varscan2
- MOSPD2 | c.15C>T p.H5= | Silent (SNP) | VAF 163/329 reads (50%) | catalogued as COSV60761167; called by muse, mutect2, varscan2
- NAALADL2 | c.1470T>C p.T490= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- PCDHA5 | c.198G>A p.A66= | Silent (SNP) | VAF 337/387 reads (87%) | catalogued as rs782275396, COSV65357826; called by muse, mutect2, varscan2
- SAMM50 | c.990G>A p.P330= | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as rs150823604; called by muse, mutect2, varscan2
- SLC16A5 | c.555C>T p.C185= | Silent (SNP) | VAF 222/223 reads (100%) | catalogued as rs770508660; called by muse, mutect2, varscan2
- SLC23A1 | c.1008C>T p.I336= | Silent (SNP) | VAF 29/202 reads (14%) | catalogued as rs373518978; called by muse, mutect2, varscan2
- SOGA1 | c.3627A>G p.K1209= | Silent (SNP) | VAF 37/641 reads (6%) | called by muse, mutect2
- STIM2 | c.1686C>G p.L562= | Silent (SNP) | VAF 105/325 reads (32%) | called by muse, mutect2, varscan2
- TMEM108 | c.636C>A p.P212= | Silent (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- TSHZ3 | c.561G>A p.E187= | Silent (SNP) | VAF 150/288 reads (52%) | called by muse, varscan2
- UGT2B11 | c.1407C>A p.P469= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as rs1437515630; called by muse, mutect2, varscan2
- UGT2B17 | c.393A>G p.A131= | Silent (SNP) | VAF 82/97 reads (85%) | called by muse, mutect2, varscan2
- ZC3H12B | c.693T>A p.T231= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100162017; called by muse, mutect2
- ZNF783 | c.684G>A p.P228= | Silent (SNP) | VAF 22/361 reads (6%) | catalogued as rs746987451, COSV65185145; called by muse, mutect2
- ZNHIT2 | c.108G>C p.R36= | Silent (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- ARHGEF4 | chr2:130915617 G>T | 5'Flank (SNP) | VAF 99/261 reads (38%) | called by muse, mutect2, varscan2
- C22orf34 | n.184G>A | RNA (SNP) | VAF 143/323 reads (44%) | called by muse, mutect2, varscan2
- CACNA1B | c.5223-1569G>A | Intron (SNP) | VAF 84/488 reads (17%) | catalogued as rs777767652, COSV53115208; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23062G>A | Intron (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.5A>G | RNA (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- IPCEF1 | c.449-48T>A | Intron (SNP) | VAF 31/44 reads (70%) | called by muse, mutect2, varscan2
- LDHA | c.126+44A>G | Intron (SNP) | VAF 54/82 reads (66%) | called by muse, mutect2, varscan2
- MAMLD1 | c.-22G>C | 5'UTR (SNP) | VAF 144/254 reads (57%) | catalogued as COSV99475676; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109910 ins C | 5'Flank (INS) | VAF 235/662 reads (35%) | called by mutect2, pindel, varscan2
- SLC5A5 | c.*10C>T | 3'UTR (SNP) | VAF 91/329 reads (28%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-12079G>A | Intron (SNP) | VAF 95/285 reads (33%) | catalogued as rs767638744, COSV100529352; called by muse, mutect2, varscan2
- XIAP | c.*5334G>T | 3'UTR (SNP) | VAF 84/225 reads (37%) | called by muse, mutect2, varscan2
